TCGA case TCGA-Q3-A5QY — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: University of Oklahoma HSC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1756244e-13bc-4ed7-8b91-005608803d91

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 58.3 years (21,277 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 416 days (1.1 years); Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 18; Tumor largest dimension diameter: 2.7 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 35 days; Days to treatment end: 92 days; Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 105, day 416.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -139 days; Days to risk factor: -139 days; Risk factors: Diabetes, NOS.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Q3-A5QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 650 mg.
  Slide TCGA-Q3-A5QY-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-Q3-A5QY-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Q3-A5QY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Tobacco smoking history indicator: 1; Alcohol history documented: No; Diabetes diagnosis indicator: Yes; History chronic pancreatitis: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 416 days; disease-specific survival: no event (censored), 416 days; progression-free interval: no event (censored), 416 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Q3-A5QY-01A-12D-A32M-01): tumor purity 0.4, ploidy 2, whole-genome doublings 0.
